Gene-level copy-number profile of tumor specimen TCGA-W5-AA2O-01A from TCGA case TCGA-W5-AA2O, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.8 years (21,118 days).
Specimen TCGA-W5-AA2O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.45b6fb5b-6907-4ce8-a3e8-78336d4a70e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W5-AA2O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb97e04e-f7b8-4633-9ef0-44073c8ae6ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,977; copy number 2: 35,571; copy number 3: 6,118; copy number 4: 105; copy number 5: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W5-AA2O-01A-11D-A416-01): tumor purity 0.76, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:63,759,892–64,490,674, 48 genes, copy number 5: C11orf95, RN7SL596P, SPINDOC, ATP5MGP1, MARK2, RNU6-1306P, RCOR2, NAA40, RNU6-45P, COX8A, AP000721.1, OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155, RPS6KA4, MIR1237, LINC02723, AP003774.1, LINC02724, AP005273.2.

Autosomal genes at a single copy (total copy number 1): 15,598. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
